Somatic mutation profile of tumor specimen MP2PRT-PASWWN-TMP1-A (aliquot MP2PRT-PASWWN-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASWWN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,069 days).
Specimen MP2PRT-PASWWN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 001a0b7b-95e0-4aab-99f9-b28dbc516d36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWWN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWWN-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79eb5bea-e9bb-46f9-883a-f2627b63c8d6

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 47/273 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX25 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 157/463 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777394498; called by muse, mutect2, varscan2
- FAM161B | c.490G>A p.E164K (on ENST00000651776; = p.E101K on NM_152445.3) | Missense Mutation (SNP) | VAF 132/441 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.373); catalogued as COSV53178212; called by muse, mutect2, varscan2
- GFRA2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs778427612, COSV60778890; called by muse, mutect2, varscan2
- MYO1D | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 17/463 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as rs1227013396, COSV59025954; called by muse, mutect2
- PCDHA2 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 243/733 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100973719; called by muse, mutect2, varscan2
- ADGRL3 | c.2632T>G p.S878A (on ENST00000506720 / NM_001322402.2; = p.S810A on NM_015236.6) | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- DCUN1D4 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.053); called by muse, mutect2
- MSI1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 137/400 reads (34%) | called by muse, mutect2, varscan2
- MYH6 | c.1552C>A p.L518M | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPAS3 | c.1387G>A p.D463N (on ENST00000356141 / NM_001164749.2; = p.D431N on NM_022123.3) | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- EFEMP1 | c.489C>T p.Y163= | Silent (SNP) | VAF 60/284 reads (21%) | catalogued as rs761107410, COSV100816704; ClinVar: benign; called by muse, mutect2, varscan2
- INPP4A | c.2931G>A p.T977= (on ENST00000074304 / NM_001134224.1; = p.T938= on NM_004027.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 98/233 reads (42%) | catalogued as rs766764597; called by muse, mutect2, varscan2
- LRRC30 | c.675G>A p.P225= | Silent (SNP) | VAF 163/419 reads (39%) | catalogued as rs1258970769, COSV67301476, COSV67302057; called by muse, mutect2, varscan2
- OR10A5 | c.732A>C p.S244= | Silent (SNP) | VAF 144/358 reads (40%) | called by muse, mutect2, varscan2
- KCNIP2 | c.74-3192A>C | Intron (SNP) | VAF 125/494 reads (25%) | called by muse, mutect2, varscan2
- TMEM145 | c.1194+746C>T | Intron (SNP) | VAF 22/375 reads (6%) | catalogued as rs377543021; called by muse, mutect2
